CCDI case PBCFSS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Testis.
https://portal.gdc.cancer.gov/cases/5f7c7e46-fae8-455b-9568-efb9401a795f

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 14.7 years (5,367 days).

Biospecimens (2 samples)
- Sample 0DR1YS: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DR1Z9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
